Somatic mutation profile of tumor specimen ALCH-B1KW-TTP1-A (aliquot ALCH-B1KW-TTP1-A-1-0-D-A710-36) from ALCHEMIST case ALCH-B1KW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 74.1 years (27,071 days).
Specimen ALCH-B1KW-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ea7d9f7-8e75-4e77-befe-fa36e924e6da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1KW-NB1-A (Blood Derived Normal), aliquot ALCH-B1KW-NB1-A-1-0-D-A710-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8698bba7-4389-4783-b314-d3a864c6e2c7

The open-access MAF lists 250 somatic variants for this specimen: 161 protein-altering or splice-affecting, 61 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 139, Silent 61, Intron 16, Nonsense Mutation 14, Frame Shift Del 5, 5'Flank 4, RNA 4, 5'UTR 2, Frame Shift Ins 2, 3'UTR 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.487T>C p.Y163H | Missense Mutation (SNP) | VAF 37/271 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786203436, COSV52661160, COSV52676168, COSV52853225, COSV53025600; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- ADAMTS7 | c.4214C>T p.A1405V | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs761495032; called by muse, mutect2, varscan2
- ALDH4A1 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 17/320 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.749); catalogued as rs370369758; called by muse, mutect2
- ANKRD39 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 41/304 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs969362682, COSV58412199; called by muse, mutect2, varscan2
- AP3B1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 101/478 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV54877546; called by muse, mutect2, varscan2
- ARID4A | c.3069T>A p.S1023R | Missense Mutation (SNP) | VAF 19/312 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV100794247; called by muse, mutect2
- ASB12 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 105/669 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62857571; called by muse, mutect2, varscan2
- ASTN2 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1189841766; called by muse, mutect2, varscan2
- BCORL1 | c.4657C>T p.P1553S | Missense Mutation (SNP) | VAF 35/307 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.901); catalogued as COSV54401659; called by muse, mutect2, varscan2
- CACNA2D4 | c.2688C>G p.N896K | Missense Mutation (SNP) | VAF 54/348 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV54950006; called by muse, mutect2, varscan2
- CARD11 | c.3335C>T p.A1112V | Missense Mutation (SNP) | VAF 19/326 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV67802447; called by muse, mutect2
- CFAP47 | c.8194G>C p.E2732Q | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV101074277; called by muse, mutect2, varscan2
- CFH | c.1730A>G p.H577R | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs141021080; called by muse, mutect2
- CHPT1 | c.640G>T p.D214Y | Missense Mutation (SNP) | VAF 19/236 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.092); catalogued as COSV57534075; called by muse, mutect2
- COL6A3 | c.3536C>A p.S1179Y | Missense Mutation (SNP) | VAF 38/550 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99040679; called by muse, mutect2
- CPA3 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 105/482 reads (22%) | catalogued as rs759623323; called by muse, mutect2, varscan2
- CT47B1 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 85/645 reads (13%) | catalogued as COSV64890654; called by mutect2, varscan2
- CT47B1 | c.285G>T p.E95D | Missense Mutation (SNP) | VAF 85/675 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.953); catalogued as COSV64890641; called by muse, mutect2, varscan2
- DCK | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as rs1305239360; called by muse, mutect2, varscan2
- EPG5 | c.3114T>A p.C1038* | Nonsense Mutation (SNP) | VAF 130/270 reads (48%) | catalogued as COSV99957011; called by muse, mutect2, varscan2
- F5 | c.2293G>A p.V765I | Missense Mutation (SNP) | VAF 23/387 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778637600, COSV100889125; called by muse, mutect2
- FGL2 | c.1255G>A p.G419S | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.068); catalogued as rs1337412711; called by muse, mutect2
- GNB2 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99309783; called by muse, mutect2
- GPC3 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 129/894 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as COSV100893007; called by muse, mutect2, varscan2
- HEPH | c.2319G>T p.K773N (on ENST00000343002; = p.K506N on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/405 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as rs759661668; called by muse, mutect2, varscan2
- HNRNPAB | c.959A>G p.Q320R (on ENST00000504898; = p.Q273R on NM_004499.4) | Missense Mutation (SNP) | VAF 76/389 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.091); catalogued as rs1227282097; called by muse, mutect2, varscan2
- HSF2 | c.469C>T p.L157F | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63773507; called by muse, mutect2, varscan2
- HYDIN | c.9952A>G p.T3318A | Missense Mutation (SNP) | VAF 34/297 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV66871485; called by muse, mutect2, varscan2
- INSL3 | c.330C>A p.N110K | Missense Mutation (SNP) | VAF 117/532 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as CM034432; called by muse, mutect2, varscan2
- KIF1A | c.971G>T p.R324M | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100239807, COSV57494733; called by muse, mutect2, varscan2
- LRRC14 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 74/302 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.846); catalogued as rs754279276; called by muse, mutect2, varscan2
- MAN2B2 | c.2436C>G p.N812K | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV53450798; called by muse, mutect2, varscan2
- MAST2 | c.3853G>A p.D1285N | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as rs1427036573; called by muse, mutect2
- MMUT | c.1091A>C p.Y364S | Missense Mutation (SNP) | VAF 26/290 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as rs563776413, CM074361, COSV51281169, COSV99222204; called by muse, mutect2
- NLRP1 | c.1748dup p.T584Dfs*7 | Frame Shift Ins (INS) | VAF 40/272 reads (15%) | catalogued as rs904995532; called by mutect2, varscan2
- NMT1 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 95/266 reads (36%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.043); catalogued as rs756082410; called by muse, mutect2, varscan2
- OR14C36 | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 26/289 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.182); catalogued as rs201498581, COSV100507697; called by muse, mutect2
- OR4C16 | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as rs376544054, COSV58940943; called by muse, mutect2
- OR8D2 | c.728C>A p.S243Y | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62488315; called by muse, mutect2, varscan2
- PAPPA2 | c.4428C>A p.N1476K | Missense Mutation (SNP) | VAF 26/273 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV62792576; called by muse, mutect2, varscan2
- PCDHB9 | c.1681G>T p.V561L | Missense Mutation (SNP) | VAF 116/554 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV53379486; called by muse, mutect2, varscan2
- PHF21A | c.464C>A p.T155N | Missense Mutation (SNP) | VAF 56/568 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV57648617; called by muse, mutect2
- POLR2M | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 24/265 reads (9%) | catalogued as rs752189072, CM157822, COSV55210815; called by muse, mutect2
- POTEJ | c.1984C>T p.L662F | Missense Mutation (SNP) | VAF 128/1088 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs113904180; called by muse, mutect2, varscan2
- PPEF1 | c.1222G>T p.E408* | Nonsense Mutation (SNP) | VAF 50/437 reads (11%) | catalogued as COSV62994999; called by muse, mutect2, varscan2
- PRAMEF11 | c.272T>A p.L91H | Missense Mutation (SNP) | VAF 62/285 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1213580637; called by muse, mutect2, varscan2
- PTCHD3 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as COSV71256319; called by muse, mutect2
- RAD54L | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 30/401 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1237327590, COSV64335645; called by muse, mutect2
- RUNX1T1 | c.973del p.D325Tfs*16 (on ENST00000265814 / NM_001198628.1; = p.D298Tfs*16 on NM_004349.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 37/207 reads (18%) | catalogued as COSV56141251; called by pindel, varscan2
- SLFN14 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 14/406 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1163391239, COSV101334657; called by muse, mutect2
- SMG6 | c.2372G>A p.R791H | Missense Mutation (SNP) | VAF 15/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1300319307, COSV99558166; called by muse, mutect2
- SRCAP | c.5333C>T p.S1778L | Missense Mutation (SNP) | VAF 21/272 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.056); catalogued as rs749054747; called by muse, mutect2
- SSC5D | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs988082938; called by muse, mutect2, varscan2
- TG | c.4362G>C p.Q1454H | Missense Mutation (SNP) | VAF 88/382 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.359); catalogued as COSV55063773; called by muse, mutect2, varscan2
- TMEM132C | c.803G>T p.R268M | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV101473771; called by muse, mutect2
- TMEM132E | c.1560C>A p.D520E (on ENST00000321639; = p.D610E on NM_001304438.2) | Missense Mutation (SNP) | VAF 67/457 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100396533; called by muse, mutect2, varscan2
- TOP3A | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200654584, COSV58177674; called by muse, mutect2
- TP53 | c.488A>T p.Y163F | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as CM942135, COSV52663142, COSV52676381; called by muse, varscan2
- TRIM67 | c.2318C>G p.T773S | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.027); catalogued as COSV64158203; called by muse, mutect2, varscan2
- TSC1 | c.611G>C p.R204P | Missense Mutation (SNP) | VAF 113/607 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs397514834, CM122076, COSV53766814, COSV53772090; ClinVar: not provided; called by muse, mutect2, varscan2
- TSHZ2 | c.2380G>A p.D794N | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1568838522; called by muse, mutect2, varscan2
- ZNF324 | c.1297G>T p.A433S | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as rs374316385; called by muse, mutect2, varscan2
- ZSWIM5 | c.2621G>A p.R874Q | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as rs761416742, COSV99869766; called by muse, mutect2
- ABCA13 | c.14311G>T p.V4771F | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- AGBL1 | c.338C>A p.S113Y | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- ALX1 | c.401G>A p.R134K | Missense Mutation (SNP) | VAF 29/394 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- APOBEC3B | c.513G>C p.W171C | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.445); called by muse, mutect2
- ARR3 | c.556del p.R186Afs*58 | Frame Shift Del (DEL) | VAF 35/304 reads (12%) | called by pindel, varscan2
- ASB12 | c.306G>T p.L102F | Missense Mutation (SNP) | VAF 104/672 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASB4 | c.916del p.I306Sfs*7 | Frame Shift Del (DEL) | VAF 46/432 reads (11%) | called by mutect2, pindel, varscan2
- ATP11C | c.1632T>A p.D544E | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BDP1 | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.039); called by muse, mutect2
- CCT2 | c.1510C>T p.L504F | Missense Mutation (SNP) | VAF 42/1324 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2
- CDH23 | c.7128C>G p.D2376E | Missense Mutation (SNP) | VAF 34/251 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHD2 | c.1952A>C p.N651T | Missense Mutation (SNP) | VAF 15/216 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- CHD8 | c.5372G>T p.R1791L (on ENST00000646647 / NM_001170629.2; = p.R1512L on NM_020920.4) | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2
- CHIC1 | c.548A>G p.N183S | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- CKAP5 | c.5477A>G p.K1826R (on ENST00000529230 / NM_001008938.4; = p.K1766R on NM_014756.3) | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- COL16A1 | c.3544C>G p.Q1182E | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- CORO1B | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- DDX55 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 75/523 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- DDX60L | c.2929G>T p.D977Y | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- DDX60L | c.2848C>A p.Q950K | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DKC1 | c.820G>C p.D274H | Missense Mutation (SNP) | VAF 98/656 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- DLG2 | c.1289G>A p.G430D | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DTX3 | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- DYRK2 | c.398G>T p.R133L (on ENST00000344096 / NM_006482.3; = p.R60L on NM_003583.4) | Missense Mutation (SNP) | VAF 108/228 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EML6 | c.2160G>C p.Q720H | Missense Mutation (SNP) | VAF 19/376 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ERBB4 | c.2593G>T p.A865S | Missense Mutation (SNP) | VAF 67/323 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM186A | c.137C>G p.S46* | Nonsense Mutation (SNP) | VAF 32/171 reads (19%) | called by muse, mutect2, varscan2
- FAM200B | c.1201C>T p.L401F | Missense Mutation (SNP) | VAF 34/308 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- FLVCR2 | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 42/638 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FRMPD3 | c.4918C>A p.Q1640K | Missense Mutation (SNP) | VAF 40/276 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- GDPD4 | c.1270A>T p.N424Y | Missense Mutation (SNP) | VAF 10/263 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- GEN1 | c.1649C>T p.P550L | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- GLMN | c.565del p.E189Kfs*16 | Frame Shift Del (DEL) | VAF 55/374 reads (15%) | called by mutect2, pindel, varscan2
- GPRIN2 | c.1009G>C p.V337L | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.804); called by muse, mutect2
- HDC | c.849C>A p.C283* | Nonsense Mutation (SNP) | VAF 71/370 reads (19%) | called by muse, mutect2, varscan2
- HEATR5A | c.458G>C p.R153P | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXA9 | c.324G>T p.M108I | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.068); called by muse, mutect2
- HSPB11 | c.269A>G p.E90G | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); called by muse, mutect2
- ICA1L | c.1306T>C p.S436P | Missense Mutation (SNP) | VAF 24/479 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2
- IFT46 | c.812A>G p.N271S (on ENST00000264021 / NM_001168618.2; = p.N322S on NM_020153.3) | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.655); called by muse, mutect2
- IGHM | c.242G>C p.G81A | Missense Mutation (SNP) | VAF 71/623 reads (11%) | SIFT tolerated (0.17); called by muse, mutect2, varscan2
- IGHV5-51 | c.55G>C p.A19P | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- IGKV2D-24 | c.130A>G p.R44G | Missense Mutation (SNP) | VAF 20/535 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, mutect2
- INPP5D | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- IP6K2 | c.538A>T p.S180C | Missense Mutation (SNP) | VAF 27/384 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); called by muse, mutect2
- IRF8 | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- ITGA1 | c.1784T>C p.L595P | Missense Mutation (SNP) | VAF 54/264 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- KMT2D | c.3957T>G p.H1319Q | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- MAGEB1 | c.230C>G p.T77S | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- MCM4 | c.1108G>C p.V370L | Missense Mutation (SNP) | VAF 24/483 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2
- MID2 | c.1364G>T p.W455L | Missense Mutation (SNP) | VAF 17/349 reads (5%) | SIFT tolerated, low confidence (0.64); PolyPhen possibly damaging (0.693); called by muse, mutect2
- MMP19 | c.1264T>A p.F422I | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NTN4 | c.613_619del p.Y205Qfs*13 | Frame Shift Del (DEL) | VAF 20/170 reads (12%) | called by mutect2, pindel
- NUP214 | c.5120G>T p.G1707V | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- NUP98 | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR2L5 | c.859A>G p.I287V | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2
- OR52H1 | c.515G>T p.R172M (on ENST00000322653; = p.R178M on NM_001005289.1) | Missense Mutation (SNP) | VAF 41/555 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); called by muse, mutect2
- OTUD4 | c.2833A>T p.K945* (on ENST00000447906 / NM_001366057.1; = p.K880* on NM_001102653.1) | Nonsense Mutation (SNP) | VAF 20/242 reads (8%) | called by muse, mutect2
- POM121L12 | c.48dup p.K17Efs*129 | Frame Shift Ins (INS) | VAF 16/138 reads (12%) | called by mutect2, pindel
- PTHLH | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- PTPRM | c.1605G>T p.Q535H | Missense Mutation (SNP) | VAF 66/355 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PXYLP1 | c.290A>T p.H97L | Missense Mutation (SNP) | VAF 154/555 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBBP6 | c.4432G>T p.D1478Y | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.725); called by muse, mutect2
- RCAN2 | c.100G>T p.G34* | Nonsense Mutation (SNP) | VAF 11/89 reads (12%) | called by muse, mutect2, varscan2
- RELN | c.7717G>A p.E2573K | Missense Mutation (SNP) | VAF 108/541 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- RGS22 | c.952T>C p.S318P | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); called by muse, mutect2
- RPS6KC1 | c.2210G>A p.S737N | Missense Mutation (SNP) | VAF 24/323 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.834); called by muse, mutect2
- RYR2 | c.4015G>A p.A1339T | Missense Mutation (SNP) | VAF 57/399 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERTM1 | c.301A>G p.T101A | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2
- SH3TC1 | c.3471G>C p.K1157N | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- SLC5A4 | c.1703A>T p.E568V | Missense Mutation (SNP) | VAF 89/374 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SMC3 | c.302T>G p.V101G | Missense Mutation (SNP) | VAF 45/570 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- SPRR3 | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 71/437 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SRL | c.1132T>G p.F378V | Missense Mutation (SNP) | VAF 63/740 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.23); called by muse, mutect2
- STK36 | c.127A>C p.K43Q | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- TBC1D25 | c.1397G>T p.R466L | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.28); called by muse, mutect2
- TECTB | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TEX10 | c.1048C>T p.R350* | Nonsense Mutation (SNP) | VAF 20/310 reads (6%) | called by muse, mutect2
- TMEM132C | c.804G>T p.R268S | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.076); called by muse, mutect2
- TMEM132D | c.2024G>T p.G675V | Missense Mutation (SNP) | VAF 29/301 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- TNFRSF14 | c.468G>T p.E156D | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TPTE | c.173+2T>A p.X58_splice | Splice Site (SNP) | VAF 44/536 reads (8%) | called by muse, mutect2
- TTN | c.7383G>C p.K2461N (on ENST00000591111; = p.K2415N on NM_003319.4) | Missense Mutation (SNP) | VAF 83/324 reads (26%) | PolyPhen benign (0.399); called by muse, mutect2, varscan2
- TTN | c.1276G>T p.V426F | Missense Mutation (SNP) | VAF 66/938 reads (7%) | PolyPhen benign (0.021); called by muse, mutect2
- TYRP1 | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 41/313 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- UVRAG | c.535C>G p.L179V | Missense Mutation (SNP) | VAF 33/249 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VPS13D | c.12967G>A p.V4323M | Missense Mutation (SNP) | VAF 73/464 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- WASHC5 | c.1777C>T p.L593F | Missense Mutation (SNP) | VAF 137/537 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- WDFY1 | c.784T>G p.S262A | Missense Mutation (SNP) | VAF 79/620 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR17 | c.1851G>A p.W617* | Nonsense Mutation (SNP) | VAF 29/287 reads (10%) | called by muse, mutect2, varscan2
- WDR64 | c.548A>T p.E183V | Missense Mutation (SNP) | VAF 48/362 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WNK3 | c.3978A>T p.K1326N | Missense Mutation (SNP) | VAF 39/300 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ZFHX4 | c.2844C>A p.C948* | Nonsense Mutation (SNP) | VAF 76/571 reads (13%) | called by muse, mutect2, varscan2
- ZNF385D | c.787C>T p.Q263* | Nonsense Mutation (SNP) | VAF 12/95 reads (13%) | called by muse, mutect2, varscan2
- ZNF408 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 56/351 reads (16%) | called by muse, mutect2, varscan2
- ZNF611 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 82/241 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ZNF626 | c.772A>C p.K258Q | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- ZNF665 | c.1001A>G p.E334G (on ENST00000600412; = p.E399G on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/176 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ACR | c.480G>T p.P160= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as COSV53361891; called by muse, mutect2, varscan2
- ADAMTS20 | c.525T>C p.Y175= | Silent (SNP) | VAF 18/538 reads (3%) | called by muse, mutect2
- AGBL1 | c.339C>T p.S113= | Silent (SNP) | VAF 28/235 reads (12%) | called by muse, mutect2, varscan2
- ANK1 | c.2886G>A p.P962= | Silent (SNP) | VAF 19/298 reads (6%) | catalogued as rs200151751, COSV55886172; called by muse, mutect2
- ANK2 | c.3528G>A p.V1176= | Silent (SNP) | VAF 34/565 reads (6%) | called by muse, mutect2
- C1GALT1C1 | c.297C>T p.F99= | Silent (SNP) | VAF 9/134 reads (7%) | called by muse, mutect2
- CCT2 | c.375C>T p.T125= | Silent (SNP) | VAF 32/1048 reads (3%) | called by muse, mutect2
- COL15A1 | c.3604C>T p.L1202= | Silent (SNP) | VAF 42/256 reads (16%) | called by muse, mutect2, varscan2
- COL6A2 | c.1512A>T p.P504= | Silent (SNP) | VAF 20/245 reads (8%) | called by muse, mutect2
- CYP2S1 | c.1089G>T p.L363= | Silent (SNP) | VAF 36/157 reads (23%) | called by muse, mutect2, varscan2
- DDRGK1 | c.174G>A p.P58= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as rs147853986, COSV63227210; called by muse, mutect2
- DNM3 | c.891G>A p.R297= | Silent (SNP) | VAF 35/417 reads (8%) | catalogued as rs769846099, COSV62455271, COSV62461375; called by muse, mutect2
- DOCK11 | c.2040C>A p.A680= | Silent (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- DUSP26 | c.174C>T p.A58= | Silent (SNP) | VAF 51/235 reads (22%) | called by muse, mutect2, varscan2
- DYDC1 | c.459T>A p.P153= | Silent (SNP) | VAF 44/270 reads (16%) | called by muse, mutect2, varscan2
- F11R | c.147C>T p.S49= | Silent (SNP) | VAF 45/298 reads (15%) | called by muse, mutect2, varscan2
- FAM90A1 | c.78C>A p.A26= | Silent (SNP) | VAF 52/612 reads (8%) | catalogued as rs752620620; called by muse, mutect2
- FRG2 | c.306C>T p.S102= | Silent (SNP) | VAF 38/734 reads (5%) | called by muse, mutect2
- FRY | c.5328C>T p.T1776= | Silent (SNP) | VAF 75/447 reads (17%) | catalogued as rs779230084; called by muse, mutect2, varscan2
- GLIPR1L1 | c.549C>T p.Y183= | Silent (SNP) | VAF 16/176 reads (9%) | catalogued as rs755736970, COSV56881178; called by muse, mutect2
- GON4L | c.6102T>C p.D2034= | Silent (SNP) | VAF 42/447 reads (9%) | called by muse, mutect2, varscan2
- HELZ2 | c.7563C>A p.L2521= (on ENST00000467148 / NM_001037335.2; = p.L1952= on NM_033405.3) | Silent (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- IDNK | c.159C>T p.L53= | Silent (SNP) | VAF 51/318 reads (16%) | catalogued as rs966346740, COSV52891572; called by muse, mutect2, varscan2
- IFIT2 | c.168A>G p.L56= | Silent (SNP) | VAF 55/364 reads (15%) | catalogued as rs754416325; called by muse, mutect2, varscan2
- IRS2 | c.2292G>T p.G764= | Silent (SNP) | VAF 44/265 reads (17%) | called by muse, mutect2, varscan2
- KIAA1217 | c.4152C>T p.A1384= | Silent (SNP) | VAF 46/251 reads (18%) | called by muse, mutect2, varscan2
- LRIG1 | c.2217C>T p.H739= | Silent (SNP) | VAF 36/147 reads (24%) | catalogued as rs556186345; called by muse, mutect2, varscan2
- LRIG2 | c.453C>G p.L151= | Silent (SNP) | VAF 35/321 reads (11%) | called by muse, mutect2
- MAGEA4 | c.543C>G p.T181= | Silent (SNP) | VAF 26/174 reads (15%) | called by muse, mutect2, varscan2
- MBNL2 | c.537G>A p.L179= | Silent (SNP) | VAF 17/86 reads (20%) | called by muse, mutect2
- MKI67 | c.8296T>C p.L2766= | Silent (SNP) | VAF 39/330 reads (12%) | catalogued as rs763018323; called by muse, mutect2, varscan2
- MNS1 | c.1452A>G p.V484= | Silent (SNP) | VAF 35/241 reads (15%) | catalogued as rs1053331225; called by muse, mutect2, varscan2
- MUC16 | c.38448C>T p.F12816= | Silent (SNP) | VAF 41/182 reads (23%) | catalogued as COSV101200578; called by muse, mutect2, varscan2
- MUC16 | c.14124A>T p.P4708= | Silent (SNP) | VAF 28/107 reads (26%) | called by muse, mutect2, varscan2
- MUC5B | c.10047C>T p.P3349= | Silent (SNP) | VAF 66/455 reads (15%) | catalogued as rs1424072978; called by muse, mutect2, varscan2
- MYO7B | c.4962C>G p.L1654= | Silent (SNP) | VAF 28/123 reads (23%) | catalogued as COSV67346100; called by muse, mutect2, varscan2
- MYORG | c.1503G>A p.A501= | Silent (SNP) | VAF 30/198 reads (15%) | catalogued as COSV99898818; called by muse, mutect2, varscan2
- NACAD | c.4077G>A p.S1359= | Silent (SNP) | VAF 32/177 reads (18%) | catalogued as rs1441040269, COSV71989472; called by muse, mutect2, varscan2
- NF1 | c.1932C>T p.S644= | Silent (SNP) | VAF 38/578 reads (7%) | called by muse, mutect2
- PATE1 | c.204A>T p.T68= | Silent (SNP) | VAF 55/378 reads (15%) | called by muse, mutect2, varscan2
- PIP4K2A | c.384C>A p.A128= | Silent (SNP) | VAF 21/274 reads (8%) | called by muse, mutect2
- PRDM9 | c.2259T>C p.C753= | Silent (SNP) | VAF 195/734 reads (27%) | catalogued as rs1226812926, COSV57009275; called by muse, varscan2
- PTPN5 | c.1650C>T p.H550= | Silent (SNP) | VAF 28/184 reads (15%) | catalogued as rs377034701; called by muse, mutect2, varscan2
- PYGO1 | c.171A>G p.P57= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as rs756985643; called by muse, mutect2, varscan2
- RGS22 | c.954C>T p.S318= | Silent (SNP) | VAF 41/162 reads (25%) | catalogued as rs1231406501, COSV100692907, COSV62668454; called by muse, mutect2
- RSPH10B2 | c.1548C>G p.L516= | Silent (SNP) | VAF 39/577 reads (7%) | catalogued as COSV51868678, COSV99786208; called by muse, mutect2
- RSPO3 | c.246T>C p.S82= | Silent (SNP) | VAF 11/153 reads (7%) | called by muse, mutect2
- SCARF1 | c.198C>T p.D66= | Silent (SNP) | VAF 21/332 reads (6%) | catalogued as rs758770965; called by muse, mutect2
- SLC6A5 | c.1677C>A p.L559= | Silent (SNP) | VAF 56/864 reads (6%) | catalogued as COSV54227026; called by muse, mutect2
- SPHKAP | c.3840G>A p.A1280= | Silent (SNP) | VAF 53/236 reads (22%) | catalogued as rs549557039; called by muse, mutect2, varscan2
- SPTA1 | c.3696C>T p.L1232= | Silent (SNP) | VAF 94/630 reads (15%) | catalogued as rs967830259, COSV63753645; called by muse, mutect2, varscan2
- TAS2R20 | c.912G>A p.Q304= | Silent (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- TBC1D8B | c.1461G>T p.G487= | Silent (SNP) | VAF 32/287 reads (11%) | called by muse, mutect2, varscan2
- TBXT | c.1245C>T p.Y415= | Silent (SNP) | VAF 34/370 reads (9%) | catalogued as rs375588439; called by muse, mutect2
- TIPARP | c.1383C>T p.D461= | Silent (SNP) | VAF 174/890 reads (20%) | catalogued as rs1370589078; called by muse, mutect2, varscan2
- TOMM40 | c.154C>A p.R52= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs576381785; called by muse, mutect2, varscan2
- TRIM2 | c.633C>T p.L211= (on ENST00000437508; = p.L238= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 22/298 reads (7%) | called by muse, mutect2
- TRRAP | c.6420C>G p.P2140= (on ENST00000359863 / NM_001244580.1; = p.P2122= on NM_003496.3) | Silent (SNP) | VAF 31/271 reads (11%) | called by muse, mutect2, varscan2
- TTN | c.5313C>T p.D1771= (on ENST00000591111; = p.D1725= on NM_003319.4) | Silent (SNP) | VAF 157/620 reads (25%) | catalogued as COSV100612355; called by muse, mutect2, varscan2
- ZNF23 | c.90G>A p.L30= | Silent (SNP) | VAF 44/304 reads (14%) | called by muse, mutect2, varscan2
- ZNHIT3 | c.351C>A p.L117= | Silent (SNP) | VAF 42/277 reads (15%) | called by muse, mutect2, varscan2
- ADGRL3 | chr4:61497282 G>C | 5'Flank (SNP) | VAF 26/382 reads (7%) | catalogued as COSV72267363; called by muse, mutect2
- AIRE | c.880-260C>T | Intron (SNP) | VAF 33/417 reads (8%) | catalogued as rs747802771; called by muse, mutect2
- AL353804.4 | chrX:73822493 T>A | 5'Flank (SNP) | VAF 26/219 reads (12%) | called by muse, mutect2, varscan2
- AL450442.1 | n.781C>G | RNA (SNP) | VAF 30/310 reads (10%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+315G>T | Intron (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- CCDC13 | c.603+2028C>G | Intron (SNP) | VAF 11/328 reads (3%) | catalogued as COSV59608489; called by muse, mutect2
- COL17A1 | c.2228-69G>T | Intron (SNP) | VAF 56/354 reads (16%) | called by muse, mutect2, varscan2
- CSMD3 | c.7885+58A>G | Intron (SNP) | VAF 38/368 reads (10%) | called by muse, mutect2, varscan2
- DNAJB14 | c.306-1607G>A | Intron (SNP) | VAF 46/249 reads (18%) | called by muse, mutect2, varscan2
- EYA4 | chr6:133531197 T>C | 3'Flank (SNP) | VAF 22/215 reads (10%) | called by muse, mutect2, varscan2
- FXYD6P3 | n.33G>A | RNA (SNP) | VAF 36/219 reads (16%) | called by muse, mutect2, varscan2
- GABRR1 | c.123-1179G>A | Intron (SNP) | VAF 18/318 reads (6%) | catalogued as rs1385958638; called by muse, mutect2
- IGFN1 | c.1241+2576G>A | Intron (SNP) | VAF 12/184 reads (7%) | catalogued as rs1163821013; called by muse, mutect2
- LGI1 | c.674-27G>A | Intron (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- LILRB1 | c.1800+334G>T | Intron (SNP) | VAF 18/168 reads (11%) | called by muse, mutect2, varscan2
- LILRB4 | chr19:54662964 G>A | 5'Flank (SNP) | VAF 84/286 reads (29%) | called by muse, mutect2, varscan2
- MLIP | c.613-11984C>G | Intron (SNP) | VAF 18/330 reads (5%) | called by muse, mutect2
- MYT1L | c.*675G>T | 3'UTR (SNP) | VAF 40/231 reads (17%) | catalogued as COSV67701292; called by muse, mutect2, varscan2
- NDE1 | chr16:15664755 G>A | 5'Flank (SNP) | VAF 11/386 reads (3%) | called by muse, mutect2
- NTRK3 | c.1586-40499G>A | Intron (SNP) | VAF 38/458 reads (8%) | called by muse, mutect2
- PGAP2 | c.166-165G>C | Intron (SNP) | VAF 63/327 reads (19%) | called by muse, mutect2, varscan2
- SAMD14 | c.823-111G>A | Intron (SNP) | VAF 62/185 reads (34%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.3632G>C | RNA (SNP) | VAF 94/553 reads (17%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-4033G>T | Intron (SNP) | VAF 152/496 reads (31%) | called by muse, mutect2, varscan2
- TLX1NB | n.1575G>C | RNA (SNP) | VAF 18/265 reads (7%) | called by muse, mutect2
- ZEB2 | c.-28C>A | 5'UTR (SNP) | VAF 107/525 reads (20%) | catalogued as rs1378549306; called by muse, mutect2, varscan2
- ZNF236 | c.-1C>T | 5'UTR (SNP) | VAF 41/418 reads (10%) | catalogued as rs781055379; called by muse, mutect2
- ZNF584 | c.292+278C>A | Intron (SNP) | VAF 12/249 reads (5%) | called by muse, mutect2
